Gene-level copy-number profile of tumor specimen TCGA-BR-A44U-01A from TCGA case TCGA-BR-A44U, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 70.0 years (25,577 days).
Specimen TCGA-BR-A44U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.4beb65e4-7d89-43ba-b3c1-b00efab7f6f9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-A44U-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/10ec6358-f346-4b30-a8ff-92e76578e67e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 6,643; copy number 2: 41,944; copy number 3: 5,557; copy number 4: 3,645; copy number 5: 245; copy number 6: 485; copy number 7: 902; copy number 8: 286; copy number 11: 9; copy number 23: 15; copy number 24: 49; copy number 26: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-A44U-01A-11D-A24C-01): tumor purity 0.62, ploidy 2.33, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr20:14,884,250–15,022,958, 4 genes: MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,003 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:112,616,440–118,881,288, 86 genes, copy number 5 (broad region; genes not listed).
- chr7:120,005,976–120,006,101, 1 gene, copy number 7: RNU1-29P.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 6–8 (broad region; genes not listed).
- chr17:26,981,694–27,315,926, 13 genes, copy number 23: AC069061.1, AC069061.2, PDLIM1P3, GTF2IP6, VN1R71P, TUFMP1, AC129926.2, AC129926.1, RPL34P31, RPS16P8, AC026254.1, MIR4522, WSB1.
- chr17:33,827,699–34,726,170, 24 genes, copy number 5 (within-gene range 3–5): AC024610.2, AC004147.4, AC024610.1, AC123769.1, TLK2P1, AC004147.1, AC004147.5, RNA5SP438, AC004147.3, AC004147.2, LINC01989, AC005549.1, CCL2, CCL7, CCL11, CCL8, AC011193.2, CCL13, CCL1, AC011193.1, C17orf102, TMEM132E, AC005691.1, AC005552.1.
- chr17:37,907,957–41,930,542, 227 genes, copy number 5–26 (within-gene range 3–26) (broad region; genes not listed).
- chr17:80,351,828–82,317,608, 118 genes, copy number 6–11 (within-gene range 1–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,062. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
